CCDI case PBBPGM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/8b2ed5db-8100-4d50-a385-e93fbd5da4a7

Demographics
Sex at birth: female; Race: white; Vital status: Dead.

Diagnoses (1)
1. Retinoblastoma, NOS: ICD-O-3 morphology code: 9510/3; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 0.2 years (68 days).

Biospecimens (3 samples)
- Sample 0DEYDK: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DEYDT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DEYEC: Tissue type: Tumor; Specimen type: Solid Tissue.
